TARGET case TARGET-10-PARHEA — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4851aafb-76b2-50d0-af8a-b09abe71c68b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 10 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 10.6 years (3,873 days); Year of diagnosis: 2007; Days to last follow up: 3,083 days (8.4 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 582 days (1.6 years); Days to first event: 582 days (1.6 years); First event: Relapse.
- Days to follow up: 3,083 days (8.4 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Positive.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 4.8 ×10³/µL.
- Day 8: Bone Marrow blast count 75%; Minimal Residual Disease (Flow Cytometry) 1.19%.
- Day 15: Bone Marrow blast count 9%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 1.6%.

Biospecimens (2 samples)
- Sample TARGET-10-PARHEA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARHEA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARHEA-09A-01D:
- Blast %: yes many

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 3083
- WBC at Diagnosis: 4.8
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 8: 1.19
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 1.6
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Positive
- BMA Blasts Day 8: 75
- BMA Blasts Day 15: 9
- BMA Blasts Day 29: 2
- Down Syndrome: No
- DNA Index: 1
- Alternate Therapy: Chemotherapy; Transplant; Other
- Alternate Therapy Other: Gleevec
- Cell of Origin: B Cell ALL
